Somatic mutation profile of tumor specimen 0DYC3K from CCDI case PBCSKM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (657 days).
Specimen 0DYC3K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e904e4cf-f59d-4e32-82f6-ab09878a1f6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYC3D (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22b2d055-689c-40a4-ad1c-120cad7c7828

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Intron 4, Nonsense Mutation 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 157/917 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 240/1452 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- RAX2 | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 193/441 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs573043030, COSV57519258; called by muse, mutect2, varscan2
- TRIM10 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 517/1095 reads (47%) | catalogued as COSV64989628; called by muse, mutect2, varscan2
- AC011455.2 | c.1425C>A p.D475E | Missense Mutation (SNP) | VAF 56/1356 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKRD11 | c.6481G>T p.A2161S | Missense Mutation (SNP) | VAF 205/1129 reads (18%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARVCF | c.2088+2T>A p.X696_splice | Splice Site (SNP) | VAF 417/819 reads (51%) | called by muse, mutect2, varscan2
- BIRC6 | c.7123G>T p.V2375L | Missense Mutation (SNP) | VAF 446/1232 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, varscan2
- FBXO15 | c.290C>A p.T97N | Missense Mutation (SNP) | VAF 207/1038 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- GCNT7 | c.604G>T p.D202Y | Missense Mutation (SNP) | VAF 139/746 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GPR45 | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 434/927 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- IZUMO3 | c.632C>T p.S211L (on ENST00000543880 / NM_001365008.2; = p.S205L on NM_001271706.1) | Missense Mutation (SNP) | VAF 182/1173 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- NRAP | c.1988C>T p.P663L (on ENST00000359988 / NM_001322945.2; = p.P628L on NM_006175.4) | Missense Mutation (SNP) | VAF 32/932 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.313); called by muse, mutect2
- TIAM1 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 44/792 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- TTC6 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 125/873 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ZBTB2 | c.91G>C p.G31R | Missense Mutation (SNP) | VAF 225/1411 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNB2 | c.1875C>T p.R625= (on ENST00000324631 / NM_201596.3; = p.R570= on NM_000724.4) | Silent (SNP) | VAF 137/1824 reads (8%) | called by muse, mutect2
- CALHM4 | c.411A>C p.A137= | Silent (SNP) | VAF 256/554 reads (46%) | called by muse, mutect2, varscan2
- GAA | c.2256C>A p.I752= | Silent (SNP) | VAF 154/1571 reads (10%) | called by muse, mutect2
- LGR6 | c.84C>A p.P28= | Silent (SNP) | VAF 176/353 reads (50%) | called by muse, mutect2, varscan2
- CAMK2D | c.160+4243T>C | Intron (SNP) | VAF 224/1256 reads (18%) | called by muse, mutect2, varscan2
- GPN1 | c.111+215G>T | Intron (SNP) | VAF 532/1051 reads (51%) | catalogued as rs1558484402; called by mutect2, varscan2
- KRTAP10-5 | c.*18G>T | 3'UTR (SNP) | VAF 486/988 reads (49%) | called by muse, mutect2, varscan2
- PSME2 | c.640-10C>A | Intron (SNP) | VAF 391/887 reads (44%) | called by muse, mutect2, varscan2
- SHMT2 | c.858-27G>T | Intron (SNP) | VAF 205/968 reads (21%) | called by muse, mutect2, varscan2
